FM case AD651 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/b45a4d03-7375-4428-ad17-c70ac3c1a800

Male, 59.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the heart. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
